Somatic mutation profile of tumor specimen HCM-BROD-1121-C71-01A (aliquot HCM-BROD-1121-C71-01A-11D-A881-36) from HCMI case HCM-BROD-1121-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.5 years (25,400 days).
Specimen HCM-BROD-1121-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56b03441-19f3-4794-a1ae-44a16f9ab476.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1121-C71-10A (Blood Derived Normal), aliquot HCM-BROD-1121-C71-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b364190a-bf51-4e52-8bed-df2fb9097a52

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Nonsense Mutation 6, Splice Region 2, Intron 2, Splice Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 76/215 reads (35%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2134C>T p.R712* (on ENST00000303395 / NM_001202435.3; = p.R701* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 80/336 reads (24%) | catalogued as rs794726730, CM024300, CX096176, COSV57668399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 204/388 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP6 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs772251291; called by muse, mutect2, varscan2
- CFAP77 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 141/573 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs568452931; called by muse, mutect2, varscan2
- FAM209A | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs778119401, COSV54766435; called by muse, mutect2, varscan2
- FKBP4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs927155815, COSV50009374; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 66/524 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, mutect2, varscan2
- ICAM5 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 108/403 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1281582816, COSV55746326; called by muse, mutect2, varscan2
- KCNH8 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as rs780804433, COSV60465399; called by muse, mutect2, varscan2
- KDR | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55766144; called by muse, mutect2, varscan2
- KRTAP12-3 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 187/963 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs200134575; called by muse, mutect2, varscan2
- MAGEB5 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 401/776 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1194249073; called by muse, mutect2, varscan2
- MAPK15 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 129/566 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782490052; called by muse, mutect2, varscan2
- MPEG1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.393); catalogued as rs984562259; called by muse, mutect2, varscan2
- MROH2A | c.3422G>A p.R1141H | Missense Mutation (SNP) | VAF 136/542 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs752495187; called by muse, varscan2
- NAV2 | c.6424C>T p.R2142C (on ENST00000396087 / NM_001244963.2; = p.R2083C on NM_145117.5) | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775604597; called by muse, mutect2, varscan2
- NOS3 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 76/536 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs369675314; called by muse, varscan2
- NPLOC4 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100480685; called by muse, mutect2
- NRXN1 | c.2500C>T p.Q834* | Nonsense Mutation (SNP) | VAF 54/255 reads (21%) | catalogued as COSV100453751; called by muse, mutect2, varscan2
- OR51S1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs776320504, COSV100437302; called by muse, mutect2, varscan2
- PAQR6 | c.609G>A p.R203= (on ENST00000292291 / NM_001272108.2; = p.R97= on NM_024897.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 39/222 reads (18%) | catalogued as COSV52744582; called by muse, mutect2, varscan2
- PIK3R6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs779211198, COSV61005470; called by muse, mutect2, varscan2
- PRX | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 159/703 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775625331; called by muse, mutect2, varscan2
- PTEN | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64299225; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2, varscan2
- RYR2 | c.7234G>A p.G2412R | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550534270, COSV100772934, COSV63696306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOHLH1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 105/417 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as rs528068735, COSV53681805; called by muse, mutect2, varscan2
- SUN3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 90/460 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs1366501433; called by muse, mutect2, varscan2
- TRHDE | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as rs1565813268; called by muse, mutect2, varscan2
- TSPO | c.183G>A p.G61= | Splice Region (SNP) | VAF 66/286 reads (23%) | catalogued as COSV100289822; called by muse, mutect2, varscan2
- ZBTB20 | c.1451C>G p.T484S (on ENST00000474710 / NM_001164342.2; = p.T411S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/488 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as rs1006124149; called by muse, mutect2, varscan2
- ZNF133 | c.403G>C p.E135Q (on ENST00000316358 / NM_001352454.2; = p.E134Q on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/494 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV60366551; called by muse, mutect2, varscan2
- ZNF619 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs374238547; called by muse, mutect2, varscan2
- ZNF836 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as rs529214922, COSV59081864; called by muse, mutect2, varscan2
- ABCA9 | c.3332G>A p.S1111N | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADAR | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 137/557 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ANO10 | c.1345T>C p.S449P | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CAMSAP3 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 103/457 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DELE1 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DENND2B | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 76/653 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM133A | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 88/385 reads (23%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 122/654 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- H3C11 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- ID2 | c.349-21_366del p.X117_splice | Splice Site (DEL) | VAF 26/250 reads (10%) | called by mutect2, pindel
- IGKV1-17 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 128/514 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KDF1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 128/496 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAFA | c.939A>C p.K313N | Missense Mutation (SNP) | VAF 146/570 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIPOL1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MN1 | c.3503_3505del p.S1168del | In Frame Del (DEL) | VAF 157/586 reads (27%) | called by mutect2, pindel, varscan2
- MSL3 | c.916G>T p.E306* (on ENST00000312196 / NM_078629.4; = p.E140* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 217/450 reads (48%) | called by muse, mutect2, varscan2
- NOX4 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- NR2F2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 148/639 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OSBPL10 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 126/520 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCK1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTEL1 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SCNN1G | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 100/337 reads (30%) | called by muse, mutect2, varscan2
- STAT1 | c.1483T>C p.W495R | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THBS2 | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.154); called by muse, mutect2
- TK2 | c.101G>T p.R34L (on ENST00000299697; = p.R90L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ADAMTS12 | c.291C>T p.H97= | Silent (SNP) | VAF 98/386 reads (25%) | catalogued as rs755549255; called by muse, mutect2, varscan2
- AMY2B | c.585C>T p.A195= | Silent (SNP) | VAF 75/313 reads (24%) | catalogued as rs749647052; called by muse, mutect2, varscan2
- FOXA2 | c.456G>A p.R152= (on ENST00000377115 / NM_153675.3; = p.R158= on NM_021784.5) | Silent (SNP) | VAF 144/585 reads (25%) | catalogued as rs200013287; called by muse, mutect2, varscan2
- GATA6 | c.1674C>T p.S558= | Silent (SNP) | VAF 112/454 reads (25%) | called by muse, varscan2
- GLUD2 | c.396C>T p.I132= | Silent (SNP) | VAF 357/714 reads (50%) | catalogued as rs750276701; called by muse, mutect2, varscan2
- GRM8 | c.279T>G p.L93= | Silent (SNP) | VAF 44/838 reads (5%) | called by muse, mutect2
- IGLON5 | c.627C>T p.R209= | Silent (SNP) | VAF 25/576 reads (4%) | catalogued as rs1158502717; called by muse, mutect2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 103/453 reads (23%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- KANK2 | c.729G>A p.R243= | Silent (SNP) | VAF 19/711 reads (3%) | catalogued as rs1442577207, COSV100763186; called by muse, mutect2
- NKX6-3 | c.255G>C p.S85= | Silent (SNP) | VAF 147/563 reads (26%) | called by muse, mutect2, varscan2
- PDE8B | c.345G>A p.V115= | Silent (SNP) | VAF 22/447 reads (5%) | called by muse, mutect2
- PREP | c.1848G>T p.A616= (on ENST00000369110; = p.A682= on NM_002726.5) | Silent (SNP) | VAF 149/563 reads (26%) | catalogued as COSV100963710; called by muse, mutect2, varscan2
- PSMC2 | c.684A>T p.A228= | Silent (SNP) | VAF 100/508 reads (20%) | catalogued as rs1054191925; called by muse, mutect2, varscan2
- TMEM128 | c.423G>T p.V141= (on ENST00000382753 / NM_001297552.2; = p.V117= on NM_032927.3) | Silent (SNP) | VAF 44/177 reads (25%) | called by muse, mutect2, varscan2
- UTS2R | c.538C>T p.L180= | Silent (SNP) | VAF 88/784 reads (11%) | called by muse, varscan2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 166/567 reads (29%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-18947G>A | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345502 C>T | 5'Flank (SNP) | VAF 101/404 reads (25%) | catalogued as rs761598566; called by muse, mutect2, varscan2
- ZNF8 | c.66+141G>A | Intron (SNP) | VAF 154/862 reads (18%) | catalogued as rs1179433727; called by muse, mutect2, varscan2
